Somatic mutation profile of tumor specimen TARGET-15-SJMLL003311-09A.1 (aliquot TARGET-15-SJMLL003311-09A.1-01D) from TARGET case TARGET-15-SJMLL003311, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.9 years (4,330 days).
Specimen TARGET-15-SJMLL003311-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24ad133f-6b32-47f3-b8f5-40ef8d885c42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMLL003311-14A (Bone Marrow Normal), aliquot TARGET-15-SJMLL003311-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b31d0a11-e00d-461d-8335-af4650d7d382

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2028C>G p.N676K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519766, COSV54042688, COSV54051954; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DACH2 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748018424, COSV100912997, COSV99058303; called by muse, mutect2, varscan2
- GTPBP4 | c.965C>A p.T322N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.151); catalogued as COSV62552413; called by mutect2, varscan2
- LGI1 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.025); catalogued as rs757480776, COSV65059189; called by muse, mutect2
- VWF | c.4579C>T p.R1527W | Missense Mutation (SNP) | VAF 129/277 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747570522; called by muse, varscan2
- PDE12 | c.1415C>A p.A472E | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2
